Somatic mutation profile of tumor specimen TCGA-VQ-A8PF-01A (aliquot TCGA-VQ-A8PF-01A-11D-A410-08) from TCGA case TCGA-VQ-A8PF, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 77.0 years (28,116 days).
Specimen TCGA-VQ-A8PF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89cc0a3b-f362-4ccf-b6d0-fdcbc487ed67.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A8PF-10B (Blood Derived Normal), aliquot TCGA-VQ-A8PF-10B-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e64b582-8e28-49c2-8acf-a3f85ef99210

The open-access MAF lists 101 somatic variants for this specimen: 77 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 22, Nonsense Mutation 6, Splice Site 2, Frame Shift Del 2, Frame Shift Ins 2, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.5161C>T p.R1721* | Nonsense Mutation (SNP) | VAF 101/232 reads (44%) | hotspot (GDC flag); catalogued as COSV61371260; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 12/96 reads (13%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, varscan2
- PIK3CA | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 8/82 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1057519930, COSV55874291, COSV55888676, COSV55926774; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- ABCA10 | c.3887T>A p.L1296H | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99287655; called by muse, mutect2
- ABCA12 | c.7583C>G p.T2528R (on ENST00000272895 / NM_173076.3; = p.T2210R on NM_015657.3) | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV99787807; called by muse, mutect2
- ADD2 | c.1174A>C p.T392P | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100034426; called by muse, mutect2
- AGRN | c.1696G>A p.V566M | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs754169694, COSV65067703; ClinVar: uncertain significance; called by muse, mutect2
- AHNAK2 | c.7147G>T p.D2383Y | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100315090; called by muse, mutect2
- AHSG | c.180G>C p.L60F | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV56609196, COSV99889765; called by muse, mutect2
- ALK | c.1993A>T p.K665* | Nonsense Mutation (SNP) | VAF 8/70 reads (11%) | catalogued as COSV101200846; called by muse, mutect2
- ALMS1 | c.7148C>T p.A2383V | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.172); catalogued as COSV100040850; called by muse, mutect2, varscan2
- ARHGEF11 | c.1213C>T p.Q405* | Nonsense Mutation (SNP) | VAF 11/43 reads (26%) | catalogued as COSV100809547; called by muse, mutect2, varscan2
- ARMC4 | c.2714T>G p.I905S | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV100536143; called by muse, mutect2, varscan2
- ATG9B | c.1693C>T p.L565F | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as COSV99871061; called by muse, mutect2, varscan2
- BRWD3 | c.4131A>C p.E1377D | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.876); catalogued as COSV100955569; called by muse, mutect2
- C1orf87 | c.269A>G p.E90G | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100966876; called by muse, mutect2
- CD14 | c.794T>G p.V265G | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100117459; called by mutect2, varscan2
- COL6A6 | c.3403G>A p.V1135M | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); catalogued as rs369579926; called by muse, mutect2, varscan2
- CPN1 | c.421-2A>T p.X141_splice | Splice Site (SNP) | VAF 6/64 reads (9%) | catalogued as COSV100962520; called by muse, mutect2
- DAGLA | c.2687C>T p.A896V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.017); catalogued as rs776522708, COSV57195606; called by mutect2, varscan2
- DIS3L2 | c.446A>G p.H149R | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs1213553749, COSV56061614; called by muse, mutect2, varscan2
- DSE | c.2133G>T p.Q711H | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV100528257; called by muse, mutect2, varscan2
- ELMOD1 | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.053); catalogued as rs761156731, COSV56191822; called by muse, mutect2, varscan2
- EML1 | c.1289G>A p.G430D | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs764557166, COSV99214350; called by muse, mutect2, varscan2
- ERCC6L | c.3575A>C p.K1192T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.034); catalogued as COSV100558967; called by muse, mutect2, varscan2
- GAK | c.1988A>C p.K663T | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100032941; called by muse, mutect2, varscan2
- GPC5 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs76285944, COSV100992411; called by muse, mutect2, varscan2
- GTF3C1 | c.976A>G p.T326A | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV62239498; called by muse, mutect2, varscan2
- HOXA9 | c.727C>G p.L243V | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100604287; called by muse, mutect2
- HRNR | c.2540C>T p.T847M | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as rs141928962; called by muse, mutect2
- ITPR1 | c.7780G>T p.A2594S (on ENST00000354582; = p.A2539S on NM_002222.7) | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100229042; called by muse, mutect2
- KCNG4 | c.456C>G p.I152M | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100376849; called by muse, mutect2, varscan2
- KLHL22 | c.1654C>T p.R552C | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56732999, COSV99839165; called by muse, mutect2
- KLHL38 | c.767A>G p.K256R | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100384208; called by muse, mutect2
- KLKB1 | c.1137C>A p.D379E | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.041); catalogued as COSV99249509; called by muse, mutect2
- LIPF | c.421A>C p.S141R | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs925738398, COSV99490076; called by muse, mutect2, varscan2
- LPP | c.41A>T p.E14V | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV100446122; called by muse, mutect2
- LRP1 | c.6929A>G p.H2310R | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV99673967; called by muse, mutect2, varscan2
- MEGF11 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as rs754160135, COSV99986682; called by muse, mutect2
- MYO7B | c.5351C>T p.P1784L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200995259, COSV101267802, COSV101267817, COSV101267898; called by mutect2, varscan2
- NEB | c.10649T>C p.I3550T | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.209); catalogued as COSV99413739; called by muse, mutect2
- NID2 | c.224T>C p.L75P | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV53502194; called by muse, mutect2
- NIN | c.3287A>G p.Q1096R | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.173); catalogued as rs201510931, COSV99811129; called by muse, mutect2, varscan2
- NLRP4 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs770052022, COSV56707343, COSV56709221; called by muse, mutect2
- NPSR1 | c.364C>T p.R122* | Nonsense Mutation (SNP) | VAF 24/47 reads (51%) | catalogued as rs202169485, COSV62197119; called by muse, mutect2, varscan2
- NR3C1 | c.1441T>A p.C481S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99196065; called by muse, mutect2, varscan2
- NRXN3 | c.1414T>A p.S472T (on ENST00000335750 / NM_001330195.2; = p.S99T on NM_004796.6) | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV100199736; called by muse, mutect2, varscan2
- OR10X1 | c.56A>C p.K19T | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as COSV63767070, COSV63768028; called by muse, mutect2
- OR5K3 | c.436G>T p.A146S | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.038); catalogued as COSV67350776; called by muse, mutect2
- PDE7B | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.635); catalogued as rs760181083, COSV100367227; called by muse, mutect2, varscan2
- PIK3C2G | c.2054G>A p.S685N (on ENST00000676171; = p.S644N on NM_004570.5) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV99848804; called by muse, mutect2
- PTK2B | c.180A>C p.K60N | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100593324; called by muse, mutect2
- PZP | c.1126C>T p.P376S | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.175); catalogued as COSV54374341; called by muse, mutect2, varscan2
- RBMS1 | c.185C>T p.T62M | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100816630; called by muse, mutect2, varscan2
- REG3G | c.334-1G>A p.X112_splice | Splice Site (SNP) | VAF 12/113 reads (11%) | catalogued as COSV55448280; called by muse, mutect2, varscan2
- RELN | c.1508G>A p.R503K | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as COSV58985842; called by muse, mutect2
- RIMS2 | c.1342T>G p.L448V (on ENST00000666250 / NM_001348490.2; = p.L256V on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.034); catalogued as COSV51669105, COSV51676746; called by muse, mutect2
- RTN4RL1 | c.985C>T p.H329Y | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.51); catalogued as COSV100486383; called by muse, mutect2
- RYR1 | c.8421G>A p.W2807* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as COSV100614130; called by muse, mutect2
- SEC31A | c.3470T>G p.L1157R (on ENST00000355196 / NM_001318120.1; = p.L1118R on NM_016211.4) | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100021340; called by muse, mutect2
- SEMA3A | c.1946G>T p.C649F | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99544712; called by muse, mutect2, varscan2
- SERINC1 | c.77G>A p.C26Y | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as rs770817621, COSV100305008; called by muse, mutect2, varscan2
- SLC15A1 | c.386T>C p.L129P | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100918170; called by muse, mutect2, varscan2
- SNAPC1 | c.872A>C p.D291A | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.239); catalogued as COSV99359071; called by muse, mutect2
- TBC1D8 | c.2195A>C p.K732T | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100964219; called by muse, mutect2
- TF | c.958G>A p.G320R | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.636); catalogued as rs749364348; called by muse, mutect2, varscan2
- THUMPD3 | c.165A>T p.E55D | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs112561603, COSV100560482; called by muse, mutect2, varscan2
- TTN | c.31028G>A p.R10343Q (on ENST00000591111; = p.R9416Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | PolyPhen benign (0); catalogued as rs759142975, COSV60106475; called by muse, mutect2, varscan2
- UNC13C | c.5023C>A p.L1675I | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.991); catalogued as COSV99510170; called by muse, mutect2, varscan2
- WASHC5 | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.171); catalogued as rs1563630839, COSV100572422; called by muse, mutect2, varscan2
- ZBTB38 | c.3407C>T p.T1136I | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1394083305, COSV100375172; called by muse, mutect2
- BCOR | c.4662dup p.D1555* (on ENST00000378444 / NM_001123385.2; = p.D1521* on NM_017745.6) | Frame Shift Ins (INS) | VAF 5/44 reads (11%) | called by mutect2, pindel
- DYNC1H1 | c.7778dup p.L2593Ffs*22 | Frame Shift Ins (INS) | VAF 8/60 reads (13%) | called by mutect2, pindel, varscan2
- LIMCH1 | c.1306C>T p.Q436* | Nonsense Mutation (SNP) | VAF 6/142 reads (4%) | called by muse, mutect2
- RASA1 | c.806_810del p.L269Pfs*11 | Frame Shift Del (DEL) | VAF 13/66 reads (20%) | called by mutect2, pindel, varscan2
- SYNRG | c.2065G>A p.D689N | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRIOBP | c.2772del p.S925Lfs*80 | Frame Shift Del (DEL) | VAF 21/112 reads (19%) | called by mutect2, pindel, varscan2
- CFAP46 | c.483C>T p.N161= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as rs181449154; called by muse, mutect2, varscan2
- CRYBG1 | c.4689G>A p.K1563= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as COSV100954353; called by muse, mutect2, varscan2
- CYP24A1 | c.1398A>C p.R466= | Silent (SNP) | VAF 4/55 reads (7%) | catalogued as COSV99397981; called by muse, mutect2
- ERBB3 | c.2571C>T p.D857= | Silent (SNP) | VAF 35/160 reads (22%) | catalogued as COSV99915466; called by muse, mutect2, varscan2
- H2AC11 | c.324C>T p.V108= | Silent (SNP) | VAF 14/125 reads (11%) | catalogued as rs779798489, COSV60362075; called by muse, mutect2, varscan2
- HIC1 | c.25T>C p.L9= | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as COSV99557621; called by muse, mutect2, varscan2
- IFNAR1 | c.726G>A p.Q242= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV99531407; called by muse, mutect2, varscan2
- KIF20A | c.2617C>T p.L873= | Silent (SNP) | VAF 3/50 reads (6%) | catalogued as COSV101203053; called by muse, mutect2
- LONP1 | c.1512C>T p.F504= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs763432896, COSV100638737, COSV62260873; called by muse, mutect2, varscan2
- MAG | c.1455C>T p.R485= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV62701448; called by muse, mutect2, varscan2
- MFAP3L | c.321C>T p.S107= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as rs199687716, COSV100852636, COSV64372030; called by muse, mutect2, varscan2
- NUP210 | c.2829C>T p.V943= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs757176224, COSV99595378; called by muse, mutect2, varscan2
- OR4A5 | c.672T>C p.T224= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV100156919; called by muse, mutect2, varscan2
- OR4K2 | c.351C>A p.A117= | Silent (SNP) | VAF 21/150 reads (14%) | catalogued as rs563942901, COSV100063954; called by muse, mutect2, varscan2
- OR51S1 | c.666C>T p.F222= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV100437320; called by muse, mutect2, varscan2
- PCDH15 | c.4758G>A p.Q1586= (on ENST00000644397 / NM_001354429.2; = p.Q1528= on NM_001142771.2) | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs368096085; ClinVar: likely benign; called by muse, mutect2, varscan2
- POTEF | c.180G>A p.K60= | Silent (SNP) | VAF 28/275 reads (10%) | catalogued as COSV100664491; called by muse, mutect2, varscan2
- PTCHD3 | c.903C>T p.F301= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs765756459, COSV101438801, COSV71256258; called by muse, mutect2, varscan2
- SHANK3 | c.3312C>T p.A1104= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs973581847, COSV99435968; called by muse, mutect2
- SLC2A7 | c.1413C>A p.G471= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV101280739; called by muse, mutect2, varscan2
- SLC4A8 | c.447G>A p.G149= | Silent (SNP) | VAF 6/97 reads (6%) | catalogued as COSV100176332, COSV60647330; called by muse, mutect2
- VWA3A | c.1560G>A p.A520= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as rs772703322, COSV55388537; called by muse, mutect2, varscan2
- LGALS12 | c.-53G>A | 5'UTR (SNP) | VAF 10/69 reads (14%) | catalogued as rs1255177996, COSV99736771; called by muse, mutect2, varscan2
- MIR520H | n.62G>C | RNA (SNP) | VAF 25/101 reads (25%) | called by muse, varscan2
